Gene-level copy-number profile of tumor specimen TCGA-CQ-A4CD-01A from TCGA case TCGA-CQ-A4CD, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mandible; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 69.8 years (25,497 days).
Specimen TCGA-CQ-A4CD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.a5bd4bf9-3bc7-41b9-b664-33f9d6b05a5f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CQ-A4CD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3c4802b3-e741-492d-a914-d29653b504bc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 2: 9,578; copy number 4: 42,303; copy number 5: 56; copy number 6: 6,364; copy number 7: 74; copy number 8: 766; copy number 11: 325; copy number 14: 273; copy number 31: 13; copy number 49: 56.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CQ-A4CD-01A-21D-A253-01): tumor purity 0.52, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 667 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:70,467,856–71,252,577, 1 gene, copy number 14 (within-gene range 6–14): SHANK2.
- chr11:70,862,790–103,895,271, 666 genes, copy number 11–49 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
